Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GB-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

L axillary dissection for melanoma Palpable nodes along incision site. FNA - melanoma. 1.65
3. ule melanoma L shoulder. Excision recurrent melanoma L axilla.

MACROSCOPIC DESCRIPTION

(

"RECURRENCE LEFT AXILLA". An irregular piece of fatty tissue 120 x 70 x 25mm with an overlying crescentic piece of skin 125 x 28mm. The concave edge of the skin ellipse is inked blue and the convex half black. There is a longitudinal curvilinear scar at least 65mm in length. On serial slicing, deep to skin within subcutis there is a circumscribed pale tumour nodule 20 x 10 x 8mm. The tumour nodule does not appear pigmented and lies 1mm from the deep margin. The nodule lies well clear of all other margins. There is a pale tumour nodule similar in appearance to the first nodule within subcutis 5mm in diameter. At the deep margin, there are up to three tan lymph nodes measuring up to 8mm in maximal diameter each. No other lesions are identified. The largest tumour nodule was sampled for tumour banking.

- A-B. Largest nodule
- C. Smaller nodule
- D. ?Lymph nodes at deep margin
- E. ?1 lymph node bisected

1CS-0-3
Melanoma, NOS 8720/3
C49.3 lymph node, axilla C49.3
Path: Site: subcutaneous, Axilla
C49.3 6/10/11

MICROSCOPIC REPORT

"RECURRENCE LEFT AXILLA". Both subcutaneous nodules consist of poorly-pigmented plump spindle cells with amphophilic cytoplasm and frequent mitoses. There are no associated definite lymph node structures but the nodules are well defined and extend close to the margin of excision. There is adjacent old fat damage and fibrosis. In blocks D and E there is deep skeletal muscle but no lymph nodes or malignancy.

SUMMARY

Left axilla - METASTATIC MELANOMA.

REPORTED BY:

HPA Discrepancy	☒	☒

Source: NCI Genomic Data Commons file 2fcf0c07-e67c-4c61-9202-87263e03f556 (TCGA-EE-A2GB.4BBF4BC4-A1B1-4DCE-8DC8-5410D7A336C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).